Somatic mutation profile of tumor specimen TCGA-CV-6951-01A (aliquot TCGA-CV-6951-01A-11D-1912-08) from TCGA case TCGA-CV-6951, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.9 years (21,166 days).
Specimen TCGA-CV-6951-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1234d323-65dd-481d-9fea-a25de28d43f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6951-10A (Blood Derived Normal), aliquot TCGA-CV-6951-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6957a50b-6109-4092-bc29-76293be54e18

The open-access MAF lists 143 somatic variants for this specimen: 108 protein-altering or splice-affecting, 35 silent.
By variant classification: Missense Mutation 95, Silent 35, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100297231; called by muse, mutect2, varscan2
- ALG2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs771801361, COSV53059958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.1847A>C p.E616A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99970884; called by muse, mutect2, varscan2
- AP3D1 | c.2827G>C p.E943Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV100643107; called by muse, mutect2
- ATIC | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); catalogued as COSV99378288; called by muse, mutect2, varscan2
- C2orf16 | c.5071G>T p.E1691* | Nonsense Mutation (SNP) | VAF 40/190 reads (21%) | catalogued as COSV100821120; called by muse, mutect2, varscan2
- CACNB1 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1268665948, COSV100703640; called by muse, mutect2, varscan2
- CDH7 | c.2201del p.A734Vfs*15 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | catalogued as COSV59886418, COSV59887407; called by mutect2, pindel, varscan2
- CDKN2A | c.439del p.A147Pfs*46 | Frame Shift Del (DEL) | VAF 26/45 reads (58%) | catalogued as COSV58721582; called by mutect2, pindel, varscan2
- CFHR2 | c.798T>G p.S266R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100804406; called by muse, mutect2, varscan2
- CHST1 | c.1056C>G p.N352K | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV100346576; called by muse, mutect2, varscan2
- CLCNKA | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100510372; called by muse, mutect2, varscan2
- COL3A1 | c.2397G>C p.E799D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV100483882; called by muse, mutect2, varscan2
- CPSF1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs965237627, COSV62941292; called by muse, mutect2, varscan2
- CREBBP | c.6689A>T p.Q2230L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV52115001, COSV99272703; called by muse, mutect2, varscan2
- CTC1 | c.3457C>T p.R1153C | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182830116, COSV59853674; called by muse, mutect2, varscan2
- DDX39A | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV54392087, COSV99660559; called by muse, mutect2, varscan2
- DHFR | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.411); catalogued as COSV101459097; called by muse, mutect2, varscan2
- EHD1 | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100277308; called by muse, mutect2, varscan2
- ELMO1 | c.2031G>A p.M677I | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs866035568, COSV100166427; called by muse, mutect2, varscan2
- EPHA7 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as COSV100992560; called by muse, mutect2, varscan2
- EPHB4 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV100639688; called by muse, mutect2
- FIGN | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as COSV100293041; called by muse, mutect2, varscan2
- GAB2 | c.1786G>A p.V596I (on ENST00000361507 / NM_080491.3; = p.V558I on NM_012296.3) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs145573768; called by muse, mutect2, varscan2
- GRTP1 | c.282C>G p.Y94* | Nonsense Mutation (SNP) | VAF 44/50 reads (88%) | catalogued as COSV100391451, COSV58149613; called by muse, mutect2, varscan2
- GULP1 | c.517-1G>T p.X173_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as rs759327196, COSV100771352; called by muse, mutect2, varscan2
- H2AC8 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99773444; called by muse, mutect2, varscan2
- HAUS1 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56363862, COSV99959609; called by muse, mutect2, varscan2
- HBS1L | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100122282; called by muse, mutect2, varscan2
- HERC1 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs759975674, COSV101497057; called by muse, mutect2, varscan2
- HMCN1 | c.9374C>G p.T3125R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99624986, COSV99637270; called by muse, mutect2, varscan2
- HSH2D | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770937633, COSV99507531; called by muse, mutect2, varscan2
- IQGAP1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs372323221; called by muse, mutect2, varscan2
- ITGB4 | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV99564981; called by muse, mutect2, varscan2
- KRT27 | c.1165T>A p.C389S | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.593); catalogued as COSV100053403; called by muse, mutect2, varscan2
- KRT6C | c.540+1G>A p.X180_splice | Splice Site (SNP) | VAF 16/97 reads (16%) | catalogued as rs370623779; called by muse, mutect2, varscan2
- LAMA2 | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101309358; called by muse, mutect2, varscan2
- LRRIQ1 | c.4943G>T p.R1648I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101280756; called by muse, mutect2, varscan2
- MAGEC3 | c.1819G>T p.A607S | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100026250; called by muse, mutect2, varscan2
- MAP3K6 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100709470; called by muse, mutect2, varscan2
- MAPK15 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.035); catalogued as rs541074717, COSV100568150; called by muse, mutect2, varscan2
- MGA | c.7724G>C p.R2575T (on ENST00000219905 / NM_001164273.1; = p.R2366T on NM_001080541.2) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54956384; called by muse, mutect2, varscan2
- MGAT4B | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as rs781374590, COSV99482460; called by muse, mutect2, varscan2
- MON2 | c.3560C>T p.T1187I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as rs1565686388, COSV99743896; called by muse, mutect2, varscan2
- MYH9 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53381589; called by muse, mutect2, varscan2
- MYO5A | c.966A>T p.Q322H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100698261; called by muse, mutect2, varscan2
- NAV1 | c.3244C>A p.Q1082K | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV55225058, COSV99819868; called by muse, mutect2, varscan2
- NICN1 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99865976; called by muse, mutect2, varscan2
- NME9 | c.736C>T p.R246* (on ENST00000333911 / NM_001349024.2; = p.R185* on NM_178130.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/209 reads (15%) | catalogued as rs764938575, COSV100444639; called by muse, mutect2, varscan2
- NOCT | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.042); catalogued as COSV99763983; called by muse, mutect2, varscan2
- NUP210L | c.2225T>G p.L742R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99669317; called by muse, mutect2, varscan2
- OR2AT4 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100532427; called by muse, mutect2, varscan2
- OR8I2 | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100136286; called by muse, mutect2, varscan2
- OTOL1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs781458945, COSV60006833; called by mutect2, varscan2
- PARP15 | c.1071G>T p.Q357H (on ENST00000464300 / NM_001113523.3; = p.Q123H on NM_152615.2) | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100117262; called by muse, mutect2, varscan2
- PDHA2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99757362; called by muse, mutect2, varscan2
- PLEC | c.532G>A p.D178N (on ENST00000322810 / NM_201380.4; = p.D68N on NM_000445.5) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100519854; called by muse, mutect2, varscan2
- PLEK | c.687T>G p.N229K | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.156); catalogued as COSV99311287; called by muse, mutect2, varscan2
- PPEF2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs867799360, COSV54427281, COSV99715123; called by muse, mutect2, varscan2
- PPFIA4 | c.3040G>A p.E1014K (on ENST00000447715; = p.E1015K on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV99691078; called by muse, mutect2, varscan2
- PPP1R3A | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 90/155 reads (58%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.564); catalogued as COSV99494644; called by muse, mutect2, varscan2
- PTAR1 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.157); catalogued as COSV100466795; called by muse, mutect2, varscan2
- PTCH1 | c.1450G>T p.G484* | Nonsense Mutation (SNP) | VAF 48/60 reads (80%) | catalogued as CM032341, COSV100110291, COSV59479120; called by muse, mutect2, varscan2
- PTH1R | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV100481208; called by muse, varscan2
- PTPA | c.592C>T p.L198F (on ENST00000337738 / NM_178001.2; = p.L163F on NM_021131.5) | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100534222; called by muse, mutect2, varscan2
- PTPN12 | c.1510A>G p.N504D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs774827761, COSV50372171; called by muse, mutect2, varscan2
- PTPRT | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61971804; called by muse, mutect2
- PZP | c.3703A>T p.T1235S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.088); catalogued as COSV99739919; called by muse, mutect2, varscan2
- RIN3 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV99380159; called by mutect2, varscan2
- RMC1 | c.1926C>G p.F642L | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99340490; called by muse, mutect2, varscan2
- RYR1 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs1032622002, COSV100617248; called by muse, mutect2, varscan2
- SCFD1 | c.863A>G p.H288R | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as COSV100356652; called by muse, mutect2, varscan2
- SCUBE2 | c.1085G>C p.C362S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100497030; called by muse, mutect2, varscan2
- SFTPA1 | c.359A>G p.Q120R | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as COSV100957217; called by muse, varscan2
- SH2D3C | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100137720; called by muse, mutect2, varscan2
- SLC22A2 | c.1047G>A p.M349I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100871087; called by muse, mutect2, varscan2
- SLC35A2 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as rs1060503676, COSV99504622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC8A3 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63520868; called by muse, mutect2, varscan2
- SPOPL | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV99699866; called by muse, mutect2, varscan2
- TAF1 | c.3655G>C p.E1219Q (on ENST00000373790 / NM_138923.4; = p.E1240Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV52106481, COSV99337302; called by muse, mutect2, varscan2
- TASOR | c.2576C>G p.S859C (on ENST00000355628 / NM_001365636.2; = p.S463C on NM_015224.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as COSV100843719, COSV62926625; called by muse, mutect2
- TBC1D32 | c.2084T>A p.L695Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99251563; called by mutect2, varscan2
- TG | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 51/151 reads (34%) | catalogued as COSV55091773, COSV99603768; called by muse, mutect2, varscan2
- TICRR | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51538204; called by muse, mutect2, varscan2
- TIGD5 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV99643719; called by muse, mutect2, varscan2
- TMEM116 | c.665G>C p.R222T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100702290; called by muse, mutect2, varscan2
- TMOD2 | c.51A>T p.E17D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99988134; called by muse, mutect2, varscan2
- TNKS2 | c.737T>A p.V246E | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861176; called by muse, mutect2, varscan2
- TOP3A | c.2834C>A p.S945Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as rs1441320893, COSV100329359; called by muse, mutect2, varscan2
- TP53 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665474, COSV52751752, COSV52987532; called by muse, mutect2, varscan2
- TRPM3 | c.3517G>A p.E1173K (on ENST00000357533 / NM_001366142.2; = p.E1028K on NM_020952.6) | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100679075; called by muse, mutect2, varscan2
- TTC33 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100531955; called by muse, mutect2, varscan2
- TYR | c.1301G>C p.R434T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as CM041868, COSV54473605; called by muse, mutect2, varscan2
- ZNF248 | c.1714A>G p.R572G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100627768; called by muse, mutect2, varscan2
- ZNF347 | c.1866G>T p.E622D | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs770964291, COSV61967884; called by muse, mutect2, varscan2
- ZNF530 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | catalogued as rs1446372761, COSV100252787; called by muse, mutect2, varscan2
- ZNF644 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV100494787; called by muse, mutect2, varscan2
- ZNF648 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1453490922, COSV60569828; called by muse, mutect2, varscan2
- ZNF669 | c.909G>C p.E303D | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV100594359; called by muse, mutect2, varscan2
- ZNF692 | c.421C>G p.H141D | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV100133975; called by muse, mutect2, varscan2
- ZNF804B | c.839A>C p.E280A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100305713, COSV100306754; called by muse, mutect2, varscan2
- ZP4 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489043564, COSV100850797; called by muse, mutect2, varscan2
- ZSWIM8 | c.3211G>T p.G1071W (on ENST00000605216 / NM_001242487.2; = p.G1076W on NM_015037.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV100014426; called by muse, mutect2, varscan2
- CDK12 | c.2603del p.N868Ifs*8 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- DPP10 | c.1870del p.V624* | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel, varscan2
- PSIP1 | c.902dup p.N301Kfs*8 | Frame Shift Ins (INS) | VAF 62/100 reads (62%) | called by mutect2, pindel, varscan2
- ZNF264 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ADAM17 | c.855C>T p.L285= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs536745843, COSV100176616, COSV60398478; called by muse, mutect2, varscan2
- C2orf16 | c.4857G>A p.E1619= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs1391673761, COSV100821119; called by muse, mutect2, varscan2
- CBFA2T2 | c.1212C>T p.V404= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV100656566; called by muse, mutect2, varscan2
- CRABP1 | c.372C>T p.G124= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs201099878, COSV55115592; called by muse, mutect2, varscan2
- CTTNBP2 | c.348C>T p.A116= | Silent (SNP) | VAF 49/277 reads (18%) | catalogued as rs757743465, COSV99355067; called by muse, mutect2, varscan2
- DHH | c.288C>T p.D96= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV57201752, COSV99908964; called by muse, mutect2, varscan2
- DMBT1 | c.1980C>T p.G660= | Silent (SNP) | VAF 61/221 reads (28%) | catalogued as rs373490476; called by muse, mutect2, varscan2
- DNAJA1 | c.726G>T p.V242= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100438663; called by muse, mutect2, varscan2
- ENGASE | c.279C>G p.L93= | Silent (SNP) | VAF 64/136 reads (47%) | catalogued as COSV100286006; called by muse, mutect2, varscan2
- FRRS1L | c.630G>A p.V210= | Silent (SNP) | VAF 63/87 reads (72%) | catalogued as COSV101643945; called by muse, mutect2, varscan2
- GRIN2D | c.1101C>T p.I367= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99617074; called by muse, mutect2, varscan2
- HSPA12B | c.513G>A p.E171= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV99654263; called by muse, mutect2, varscan2
- HYDIN | c.10059G>A p.Q3353= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV101158869; called by muse, mutect2, varscan2
- KNTC1 | c.198A>G p.S66= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1430429096, COSV100338903; called by muse, mutect2
- MEOX2 | c.324C>A p.L108= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as rs1384759810, COSV100012615; called by muse, mutect2, varscan2
- MROH7 | c.2358C>T p.L786= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as rs778383168, COSV100274163; called by muse, mutect2, varscan2
- MYBPC1 | c.567C>T p.D189= (on ENST00000550270 / NM_206820.2; = p.D214= on NM_002465.4) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs758364410, COSV100638321; called by muse, mutect2, varscan2
- OR2T3 | c.918G>A p.L306= | Silent (SNP) | VAF 45/429 reads (10%) | catalogued as rs764496272, COSV100612980, COSV100613467; called by muse, mutect2, varscan2
- P2RY2 | c.303C>T p.F101= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV100232895; called by muse, mutect2, varscan2
- PCDHAC1 | c.942C>T p.D314= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as rs562081561, COSV99170167; called by muse, mutect2, varscan2
- PGBD1 | c.1236C>G p.L412= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs941987594, COSV99460354; called by muse, mutect2, varscan2
- PPP6R3 | c.606G>T p.S202= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV99677777; called by muse, mutect2, varscan2
- RAB11FIP2 | c.645T>C p.F215= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV100843151; called by muse, mutect2, varscan2
- RNF8 | c.1224A>G p.E408= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100009945; called by muse, mutect2, varscan2
- SAMD9L | c.3834G>A p.L1278= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100561214; called by muse, mutect2, varscan2
- SLC35D1 | c.412C>T p.L138= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV52432103; called by muse, mutect2, varscan2
- SPTBN5 | c.4791C>A p.I1597= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs771940150, COSV100312374, COSV58024198; called by muse, mutect2, varscan2
- TKTL2 | c.399A>T p.A133= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV99761817; called by muse, mutect2, varscan2
- WDR92 | c.591C>G p.L197= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as COSV99718552; called by muse, mutect2, varscan2
- ZBTB8OS | c.93G>A p.A31= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as rs1245217319, COSV100542434; called by muse, varscan2
- ZMYM6 | c.3825A>G p.L1275= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs759777720, COSV100593376; called by muse, mutect2, varscan2
- ZNF33B | c.2055A>G p.R685= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100847811; called by muse, mutect2, varscan2
- ZNF479 | c.525T>C p.D175= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100483157; called by muse, mutect2, varscan2
- ZNF524 | c.639C>T p.L213= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV99684770; called by muse, mutect2, varscan2
- ZSWIM7 | c.39G>C p.L13= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99890480; called by muse, mutect2
